Surgical pathology report (de-identified scan), TCGA case TCGA-06-0157, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0157-01A (Primary Tumor).

PATHOLOGICAL DIAGNOSIS:

BRAIN BIOPSY, LEFT PULVINAR: GLIOBLASTOMA (MIB-1: ABOUT 10%).

Operation/Specimen: Mass left pulvinar

Clinical History and Pre-Op Dx: Tumor left pulvinar

GROSS PATHOLOGY: Multiple tissue fragments 1.5 x 1.5 x 1.0 cm. Frozen
section diagnosis: glioma. All submitted in #1-5.

MICROSCOPIC: Sections show a high grade glioma with hypercellularity
pleomorphism. Mitotic figures and microvascular endothelial
hyperplasia. Fragments of necrotic tissue are also present. The MIB-1
labeling index of the tumor cells is about 10%.

Source: NCI Genomic Data Commons file d9829103-8aa1-44c4-9fd9-db01f4e832d7 (TCGA-06-0157.2FA84B5C-8326-4A85-959A-0B0C03BB465C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).